Gene-level copy-number profile of tumor specimen TCGA-FU-A40J-01A from TCGA case TCGA-FU-A40J, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 38.8 years (14,182 days).
Specimen TCGA-FU-A40J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.2ff5e946-5983-449d-8c74-9aff16bcf243.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FU-A40J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/072b3e94-b724-4e0d-8bb8-3b6a1d8ceb3e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 744; copy number 2: 5,717; copy number 3: 20,163; copy number 4: 12,770; copy number 5: 15,471; copy number 6: 4,752; copy number 9: 166; copy number 23: 30; copy number 104: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FU-A40J-01A-11D-A242-01): tumor purity 0.65, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 197 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,292,233–127,292,440, 1 gene, copy number 104: AC018714.1.
- chr20:31,257,664–36,232,799, 196 genes, copy number 9–23 (within-gene range 2–23) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
